Somatic mutation profile of tumor specimen TCGA-CF-A9FF-01A (aliquot TCGA-CF-A9FF-01A-11D-A38G-08) from TCGA case TCGA-CF-A9FF, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 52.6 years (19,195 days).
Specimen TCGA-CF-A9FF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95080c19-f193-4bb9-b409-a3d7d8db7de9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CF-A9FF-10A (Blood Derived Normal), aliquot TCGA-CF-A9FF-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/255e12ca-fb21-45b7-91c7-f803b39ebde7

The open-access MAF lists 160 somatic variants for this specimen: 118 protein-altering or splice-affecting, 36 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 91, Silent 36, Nonsense Mutation 20, Frame Shift Del 5, 3'UTR 2, 5'UTR 2, Splice Site 1, 5'Flank 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL2 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 28/67 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55452713, COSV55455449; called by muse, mutect2, varscan2
- FGFR3 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 19/39 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913483, CM950470, COSV53390026; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MFRP | chr11:119345563 del G | 5'Flank (DEL) | VAF 12/36 reads (33%) | catalogued as rs587776596, CD052468, COSV64129114; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 19/57 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAM15 | c.460G>C p.E154Q | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.948); catalogued as rs773958488, COSV55060488; called by muse, mutect2, varscan2
- ADAMTS14 | c.412G>T p.E138* | Nonsense Mutation (SNP) | VAF 16/37 reads (43%) | catalogued as COSV100941327; called by muse, mutect2, varscan2
- ANKRD20A4P | c.1226C>T p.S409F | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs766257198, COSV100628389; called by muse, mutect2, varscan2
- APOB | c.8977G>C p.D2993H | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV51938081, COSV51941541; called by muse, mutect2, varscan2
- ARID2 | c.1807del p.A603Lfs*44 | Frame Shift Del (DEL) | VAF 47/173 reads (27%) | catalogued as COSV100536846, COSV57603528; called by mutect2, pindel, varscan2
- BPIFB3 | c.458C>G p.S153* | Nonsense Mutation (SNP) | VAF 21/54 reads (39%) | catalogued as COSV100972280; called by muse, mutect2, varscan2
- CASC3 | c.1469G>A p.R490Q | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.59); catalogued as rs573143979, COSV52868170; called by muse, varscan2
- CCDC178 | c.248G>C p.R83P | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55781497; called by muse, mutect2, varscan2
- CCDC47 | c.711G>A p.M237I | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.402); catalogued as COSV56723501; called by muse, mutect2, varscan2
- CCNO | c.116G>A p.R39K | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.113); catalogued as rs1454275170, COSV99248067; called by muse, mutect2, varscan2
- CDKN1A | c.28C>T p.Q10* | Nonsense Mutation (SNP) | VAF 7/31 reads (23%) | catalogued as COSV55186863; called by muse, mutect2, varscan2
- CENPI | c.428C>G p.S143C | Missense Mutation (SNP) | VAF 6/156 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.625); catalogued as COSV54501254, COSV54503958, COSV54506956; called by muse, mutect2
- CEP131 | c.3034G>A p.E1012K (on ENST00000269392 / NM_001319228.2; = p.E1009K on NM_014984.4) | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.544); catalogued as rs1489491483, COSV53953998; called by muse, mutect2, varscan2
- CEP192 | c.5392C>G p.Q1798E | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV58066687; called by muse, mutect2, varscan2
- CHPF2 | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.472); catalogued as COSV50393084; called by muse, mutect2, varscan2
- COL4A4 | c.3868G>A p.E1290K | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.346); catalogued as rs865923173, COSV100306111; called by muse, mutect2
- CPA3 | c.1102G>A p.D368N | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.091); catalogued as COSV56045911; called by muse, mutect2, varscan2
- CSNK1D | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs774858511, COSV53925579; called by muse, mutect2, varscan2
- DCC | c.2597A>G p.D866G | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59113504; called by muse, mutect2
- DCT | c.307G>T p.G103C | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65469853; called by muse, mutect2, varscan2
- DIAPH2 | c.723G>A p.M241I | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61277003; called by muse, mutect2, varscan2
- DISP2 | c.823G>C p.E275Q | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV51127602; called by muse, mutect2, varscan2
- DNAH11 | c.1157T>G p.V386G | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as COSV60964115; called by muse, mutect2, varscan2
- DNAI4 | c.2056C>G p.H686D | Missense Mutation (SNP) | VAF 20/226 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64030137; called by muse, mutect2
- DNAJC13 | c.5491C>T p.Q1831* | Nonsense Mutation (SNP) | VAF 14/51 reads (27%) | catalogued as COSV99606481; called by muse, mutect2, varscan2
- DST | c.389C>G p.S130C | Missense Mutation (SNP) | VAF 60/201 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as rs1213848467; called by muse, mutect2, varscan2
- ELMO1 | c.317A>G p.D106G | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.334); catalogued as COSV60310789; called by muse, mutect2, varscan2
- EPHA4 | c.2491C>T p.Q831* | Nonsense Mutation (SNP) | VAF 10/41 reads (24%) | catalogued as COSV99915446; called by muse, mutect2, varscan2
- EPHA5 | c.1406C>A p.P469Q | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as COSV99895849; called by muse, mutect2
- EPHA5 | c.1405C>A p.P469T | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV99895852; called by muse, mutect2
- EXOC4 | c.1177C>G p.L393V | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.219); catalogued as COSV54105990; called by muse, mutect2, varscan2
- FAM177A1 | c.335C>A p.S112* (on ENST00000382406 / NM_001289022.2; = p.S135* on NM_173607.5) | Nonsense Mutation (SNP) | VAF 62/188 reads (33%) | catalogued as COSV99805659; called by muse, mutect2, varscan2
- FAP | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV51863899; called by muse, mutect2, varscan2
- FAT4 | c.12313C>T p.Q4105* | Nonsense Mutation (SNP) | VAF 45/136 reads (33%) | catalogued as COSV100627168; called by muse, mutect2, varscan2
- FSIP2 | c.18226G>A p.D6076N | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as rs1371355209, COSV58080718, COSV58090717; called by muse, mutect2, varscan2
- FXR2 | c.1427G>A p.R476Q | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.16); PolyPhen benign (0.111); catalogued as rs1310981992, COSV51468639; called by muse, mutect2, varscan2
- GFRAL | c.459A>C p.K153N | Missense Mutation (SNP) | VAF 44/147 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61232449, COSV61235425; called by muse, mutect2, varscan2
- GLTP | c.102C>T p.F34= | Splice Region (SNP) | VAF 5/13 reads (38%) | catalogued as rs367798721, COSV59173158; called by muse, mutect2, varscan2
- GOLGA4 | c.5177C>T p.S1726F | Missense Mutation (SNP) | VAF 6/145 reads (4%) | SIFT tolerated (0.57); PolyPhen benign (0.1); catalogued as COSV62711749; called by muse, mutect2
- GTF2B | c.551C>A p.S184* | Nonsense Mutation (SNP) | VAF 32/80 reads (40%) | catalogued as COSV100980485; called by muse, mutect2, varscan2
- HIP1 | c.2191G>A p.E731K | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.03); catalogued as COSV61187995; called by muse, mutect2, varscan2
- HRNR | c.2026G>A p.G676S | Missense Mutation (SNP) | VAF 113/278 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.178); catalogued as rs141565920; called by muse, mutect2
- HTR4 | c.286C>G p.R96G | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.927); catalogued as COSV58798362; called by muse, mutect2, varscan2
- IL37 | c.492G>A p.W164* | Nonsense Mutation (SNP) | VAF 16/58 reads (28%) | catalogued as COSV99635966; called by muse, varscan2
- IL37 | c.571G>T p.D191Y | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as COSV54491727; called by muse, varscan2
- IL37 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.506); catalogued as COSV54491745; called by muse, varscan2
- IRAK1BP1 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as COSV64048441; called by muse, mutect2, varscan2
- IRX5 | c.374C>T p.T125M | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100315611; called by muse, mutect2
- KAT8 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54896227, COSV99571049; called by muse, mutect2, varscan2
- LIFR | c.3113A>C p.N1038T | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV54693246; called by muse, mutect2
- LRP2 | c.11794G>A p.E3932K | Missense Mutation (SNP) | VAF 49/96 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55560206; called by muse, mutect2, varscan2
- LRRC18 | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs773741095, COSV53284389; called by muse, mutect2, varscan2
- LRRC74A | c.895C>T p.R299* | Nonsense Mutation (SNP) | VAF 33/72 reads (46%) | catalogued as rs200930269, COSV53611406; called by muse, mutect2, varscan2
- MAP4K3 | c.726-1G>A p.X242_splice | Splice Site (SNP) | VAF 9/41 reads (22%) | catalogued as COSV55714775; called by muse, mutect2, varscan2
- MAST4 | c.3347C>G p.S1116C (on ENST00000403625 / NM_001164664.2; = p.S927C on NM_015183.3) | Missense Mutation (SNP) | VAF 5/141 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55131038; called by muse, mutect2
- MROH7 | c.195G>C p.L65F | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.964); catalogued as COSV59874092; called by muse, mutect2, varscan2
- MYCBP2 | c.5956G>C p.E1986Q (on ENST00000357337; = p.E2024Q on NM_015057.5) | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV62026715; called by muse, mutect2, varscan2
- NBR1 | c.62C>G p.S21C | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1235278187, COSV57833569; called by muse, mutect2
- NIPA2 | c.142C>T p.Q48* | Nonsense Mutation (SNP) | VAF 22/60 reads (37%) | catalogued as COSV100508724; called by muse, mutect2, varscan2
- NISCH | c.3142G>A p.A1048T | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV61900919; called by muse, mutect2, varscan2
- NKX2-2 | c.395G>C p.R132P | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1421376027, COSV101010480; called by muse, mutect2
- NSF | c.1633C>T p.P545S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.224); catalogued as rs1481268654, COSV56575406; called by muse, mutect2, varscan2
- NT5DC3 | c.260C>T p.S87L | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as rs1372718928, COSV101230996, COSV67321368; called by muse, mutect2, varscan2
- NUP205 | c.4073C>T p.S1358L | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV53661507; called by muse, mutect2, varscan2
- OBSCN | c.12607G>A p.E4203K | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.949); catalogued as COSV52790380; called by muse, mutect2, varscan2
- OR5M10 | c.578G>C p.R193P | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.196); catalogued as COSV73242359; called by muse, mutect2, varscan2
- PCDHA8 | c.1645G>A p.V549M | Missense Mutation (SNP) | VAF 9/157 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.858); catalogued as rs1481565497, COSV65328405; called by muse, mutect2
- PCNT | c.4333G>A p.E1445K | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV64030025; called by muse, mutect2, varscan2
- PHF20 | c.1246C>T p.P416S | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV59186948; called by muse, mutect2, varscan2
- PHLDA3 | c.287C>G p.A96G | Missense Mutation (SNP) | VAF 51/131 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV66210878; called by muse, mutect2, varscan2
- PHLDB1 | c.3883G>A p.E1295K | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV99874136; called by muse, mutect2
- PI4KA | c.1658C>T p.S553L | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.023); catalogued as rs371872004; called by muse, mutect2, varscan2
- PIK3R6 | c.490G>T p.V164L | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.054); catalogued as rs1346755039, COSV61004038; called by muse, mutect2, varscan2
- PLXNB1 | c.3491T>A p.V1164D | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99602186; called by muse, mutect2
- PPARG | c.1424C>T p.T475M (on ENST00000287820 / NM_015869.5; = p.T445M on NM_005037.7) | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1479145908, COSV55141227; called by muse, mutect2, varscan2
- PPP1R3B | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.115); catalogued as COSV60099792; called by muse, mutect2, varscan2
- PPP3CC | c.925G>C p.D309H | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51501775; called by muse, mutect2
- PRRC2A | c.2263C>T p.P755S | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.644); catalogued as COSV65687637; called by muse, varscan2
- PRRC2C | c.7837C>T p.Q2613* (on ENST00000367742; = p.Q2611* on NM_015172.4) | Nonsense Mutation (SNP) | VAF 3/22 reads (14%) | catalogued as COSV100144612; called by muse, mutect2
- QARS1 | c.2060G>A p.C687Y | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs1335625299, COSV60275463; called by muse, mutect2, varscan2
- RAB4B | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.617); catalogued as rs747053848, COSV63824679; called by muse, mutect2, varscan2
- RBM27 | c.2827C>T p.R943* | Nonsense Mutation (SNP) | VAF 16/40 reads (40%) | catalogued as COSV99505623; called by muse, mutect2, varscan2
- RC3H2 | c.2161G>C p.D721H | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.839); catalogued as COSV61801171; called by muse, mutect2, varscan2
- RGMA | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); catalogued as rs1462270310, COSV61235219; called by muse, mutect2, varscan2
- RGMA | c.787G>T p.E263* | Nonsense Mutation (SNP) | VAF 11/38 reads (29%) | catalogued as COSV100224062, COSV61233743; called by muse, mutect2, varscan2
- RNASEH2B | c.585C>G p.F195L | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV60746911; called by muse, mutect2, varscan2
- RREB1 | c.1204C>T p.Q402* | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | catalogued as COSV58565678; called by muse, mutect2, varscan2
- SCML1 | c.57C>A p.Y19* | Nonsense Mutation (SNP) | VAF 9/16 reads (56%) | catalogued as COSV101193893; called by muse, mutect2, varscan2
- SEMA5B | c.969G>C p.K323N | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV52101579; called by muse, mutect2, varscan2
- SGSM2 | c.493C>A p.P165T | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV52159214; called by muse, mutect2, varscan2
- SH3KBP1 | c.1184T>C p.V395A | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.6); catalogued as COSV65642684; called by muse, mutect2
- SLC35B2 | c.594G>A p.W198* | Nonsense Mutation (SNP) | VAF 44/110 reads (40%) | catalogued as COSV99240852; called by muse, mutect2, varscan2
- SLC39A14 | c.1148G>A p.G383E | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV51485300; called by muse, mutect2, varscan2
- SOX5 | c.345del p.G116Vfs*24 | Frame Shift Del (DEL) | VAF 27/75 reads (36%) | catalogued as COSV58627164; called by mutect2, pindel, varscan2
- SPECC1 | c.769C>T p.L257F | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.065); catalogued as rs996460034, COSV54961033; called by muse, mutect2, varscan2
- SPNS1 | c.1216C>A p.L406M | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57955347; called by muse, mutect2, varscan2
- SPOP | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV61653748; called by muse, mutect2, varscan2
- SPTAN1 | c.853C>T p.R285* | Nonsense Mutation (SNP) | VAF 48/86 reads (56%) | catalogued as COSV63989520; called by muse, mutect2, varscan2
- TASOR2 | c.3935C>G p.S1312* | Nonsense Mutation (SNP) | VAF 45/149 reads (30%) | catalogued as COSV100049927; called by muse, mutect2, varscan2
- TMEM248 | c.791C>T p.S264L | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as COSV58577760; called by muse, mutect2, varscan2
- TMTC2 | c.1206C>G p.I402M | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.271); catalogued as COSV58274268, COSV58280401; called by muse, mutect2, varscan2
- TRIP12 | c.371C>G p.S124C | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.971); catalogued as COSV52267035; called by muse, mutect2, varscan2
- TSC1 | c.831_832del p.H279Pfs*20 | Frame Shift Del (DEL) | VAF 10/27 reads (37%) | catalogued as rs118203455; called by pindel, varscan2
- UBR2 | c.4148C>T p.S1383L | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV65750800; called by muse, mutect2, varscan2
- UNC79 | c.3064C>G p.Q1022E (on ENST00000393151 / NM_001346218.2; = p.Q845E on NM_020818.5) | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as COSV56395405; called by muse, mutect2
- USP48 | c.1291C>T p.Q431* | Nonsense Mutation (SNP) | VAF 30/110 reads (27%) | catalogued as COSV100379421; called by muse, mutect2, varscan2
- USP9Y | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT deleterious (0.04); PolyPhen benign (0.184); catalogued as COSV59099768; called by muse, mutect2, varscan2
- VPS13A | c.9343G>A p.E3115K | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV64332038; called by muse, mutect2, varscan2
- WDR44 | c.2596G>A p.E866K | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as COSV54165335; called by muse, mutect2, varscan2
- WDR90 | c.1516G>C p.D506H | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV53471957; called by muse, mutect2, varscan2
- ZFYVE21 | c.292G>C p.E98Q | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.588); catalogued as rs1331941041, COSV53694306; called by muse, mutect2, varscan2
- CAMLG | c.179_182del p.E60Vfs*13 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | called by mutect2, pindel
- CDKN1A | c.176_191del p.L59Pfs*84 | Frame Shift Del (DEL) | VAF 10/41 reads (24%) | called by mutect2, pindel, varscan2
- SPATA31A3 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.548); called by mutect2, varscan2
- SUPT20HL2 | c.1985G>T p.G662V | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ADPRHL1 | c.972C>T p.L324= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs372483819, COSV62909835; called by muse, mutect2, varscan2
- AGXT | c.138C>A p.I46= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV56754781; called by muse, mutect2, varscan2
- APC | c.3297T>G p.V1099= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as COSV57356163; called by muse, mutect2, varscan2
- BTBD11 | c.1326C>G p.L442= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as COSV55027968; called by muse, varscan2
- CARMIL3 | c.3585C>T p.D1195= | Silent (SNP) | VAF 26/87 reads (30%) | catalogued as rs749092838, COSV57727153; called by muse, mutect2, varscan2
- COL3A1 | c.3819G>A p.K1273= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as rs1219896056, COSV58591589; ClinVar: likely benign; called by muse, mutect2, varscan2
- COQ8A | c.1656C>G p.V552= | Silent (SNP) | VAF 38/97 reads (39%) | catalogued as COSV62014098; called by muse, mutect2, varscan2
- CRYBB1 | c.537C>T p.F179= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV53233803; called by mutect2, varscan2
- CSNK1D | c.669G>A p.Q223= | Silent (SNP) | VAF 51/104 reads (49%) | catalogued as COSV53925544; called by muse, mutect2, varscan2
- DOP1A | c.2644T>C p.L882= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as rs746112037, COSV52712675; called by muse, mutect2, varscan2
- FAM184A | c.2475C>G p.L825= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as COSV58855930, COSV58857521; called by muse, mutect2, varscan2
- FANCE | c.1101C>G p.L367= | Silent (SNP) | VAF 80/223 reads (36%) | catalogued as COSV57690343; called by muse, mutect2, varscan2
- FNDC11 | c.936C>T p.P312= | Silent (SNP) | VAF 43/118 reads (36%) | catalogued as rs772931052, COSV64443048; called by muse, mutect2, varscan2
- FUT1 | c.930C>T p.F310= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV59568949; called by muse, mutect2, varscan2
- GRIN2A | c.1945C>T p.L649= | Silent (SNP) | VAF 65/126 reads (52%) | catalogued as CM1211494, COSV58020392, COSV58055559, COSV58057887; called by muse, mutect2, varscan2
- H2AC8 | c.34C>A p.R12= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV55127224; called by muse, mutect2, varscan2
- HIGD2A | c.219G>A p.Q73= | Silent (SNP) | VAF 6/142 reads (4%) | catalogued as COSV51257754; called by muse, mutect2
- KDR | c.3702G>C p.V1234= | Silent (SNP) | VAF 22/84 reads (26%) | catalogued as COSV55762818, COSV55768844; called by muse, mutect2, varscan2
- LIG4 | c.2037G>A p.E679= | Silent (SNP) | VAF 27/77 reads (35%) | catalogued as COSV100799793, COSV63597405; called by muse, mutect2, varscan2
- LRRC4C | c.321G>A p.L107= | Silent (SNP) | VAF 3/39 reads (8%) | catalogued as COSV99540010; called by muse, mutect2
- MORC4 | c.1695A>G p.K565= | Silent (SNP) | VAF 26/35 reads (74%) | catalogued as COSV55243929; called by muse, mutect2, varscan2
- NFKBIZ | c.2118G>A p.L706= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV58200955; called by muse, mutect2, varscan2
- NGEF | c.1539C>G p.L513= | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as COSV99887896; called by muse, mutect2
- NYAP2 | c.1464C>T p.V488= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV56009606; called by muse, mutect2, varscan2
- PHACTR1 | c.681G>A p.V227= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as COSV60671963; called by muse, mutect2, varscan2
- RGMA | c.264G>A p.R88= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as COSV61235228; called by muse, mutect2, varscan2
- RPS6KA6 | c.1212C>T p.I404= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as COSV53122150; called by muse, mutect2, varscan2
- RTEL1 | c.2913G>C p.L971= | Silent (SNP) | VAF 44/96 reads (46%) | catalogued as COSV58896730; called by muse, mutect2, varscan2
- SLC22A14 | c.174G>C p.A58= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as COSV56198241; called by muse, mutect2, varscan2
- TBL2 | c.642C>T p.I214= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV59787482; called by muse, mutect2, varscan2
- TRIP6 | c.972G>A p.R324= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV52342339; called by muse, mutect2, varscan2
- TRPC4AP | c.606G>A p.K202= | Silent (SNP) | VAF 29/83 reads (35%) | catalogued as COSV52681532; called by muse, mutect2, varscan2
- TSPOAP1 | c.2400C>G p.L800= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV52111883; called by muse, mutect2, varscan2
- VWA5A | c.1365C>T p.L455= | Silent (SNP) | VAF 64/160 reads (40%) | catalogued as COSV64413269; called by muse, mutect2, varscan2
- VWA8 | c.1131A>G p.V377= | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as COSV55699608; called by muse, mutect2, varscan2
- YJU2 | c.390G>A p.L130= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs1410256472, COSV99508186; called by muse, mutect2, varscan2
- B4GALNT1 | c.*1316C>T | 3'UTR (SNP) | VAF 14/53 reads (26%) | catalogued as COSV57543419; called by muse, mutect2, varscan2
- CDKL1 | c.367-772G>C | Intron (SNP) | VAF 4/10 reads (40%) | catalogued as rs766056151, COSV99367180; called by muse, mutect2, varscan2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 11/24 reads (46%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2, varscan2
- UBXN6 | c.-2C>A | 5'UTR (SNP) | VAF 5/9 reads (56%) | catalogued as rs776558429, COSV100011725; called by muse, mutect2, varscan2
- ZNF117 | c.*2C>T | 3'UTR (SNP) | VAF 8/34 reads (24%) | catalogued as rs1375902297, COSV99275151; called by muse, mutect2, varscan2
